Gene-level copy-number profile of tumor specimen TCGA-86-7701-01A from TCGA case TCGA-86-7701, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 66.3 years (24,209 days).
Specimen TCGA-86-7701-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.8cdc412c-9908-473f-97fe-8516ed48ba8c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-7701-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/42da2dd7-5487-4793-a24d-8d38b6a364b7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 560; copy number 2: 25,122; copy number 3: 18,795; copy number 4: 11,453; copy number 5: 1,070; copy number 6: 2,338; copy number 7: 429; copy number 8: 34; copy number 9: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-7701-01A-11D-2166-01): tumor purity 0.42, ploidy 2.97, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,890 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–154,993,111, 518 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:230,990,324–242,160,153, 289 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:141,660,536–143,177,617, 42 genes, copy number 6 (within-gene range 3–6): LINC02618, TPT1P3, AC112771.1, RNF7, AC112504.2, GRK7, AC112504.3, HMGN2P25, ATP1B3, RNU6-509P, ATP1B3-AS1, AC112504.1, TFDP2, AC133435.1, RNU6-425P, GK5, XRN1, RNU6-1294P, RNU1-100P, ATR, AC109992.1, AC109992.2, RPL6P9, RNA5SP143, PLS1, PLS1-AS1, RN7SKP25, AC072028.1, TRPC1, RNU7-47P, PCOLCE2, AC021074.1, AC021074.3, PAQR9, AC021074.2, PAQR9-AS1, U2SURP, AC026304.1, AC018450.2, CHST2, AC018450.1, PBX2P1.
- chr3:145,523,538–146,251,179, 10 genes, copy number 7: LARP7P4, GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4.
- chr3:149,517,235–155,309,807, 105 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr3:156,037,701–156,539,138, 1 gene, copy number 6 (within-gene range 3–6): KCNAB1.
- chr3:156,143,570–156,540,627, 1 gene, copy number 6 (within-gene range 3–6): AC091607.2.
- chr3:156,441,157–172,427,089, 217 genes, copy number 6 (broad region; genes not listed).
- chr3:175,369,540–179,147,973, 46 genes, copy number 6: MIR4789, RNU6-1233P, AC008180.3, RNU4-91P, AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1, AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1, LINC01208, MIR7977, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC110992.1, AC117453.1, KCNMB2, AC117457.1, LINC01014, RNA5SP148, PPIAP75, KCNMB2-AS1, ZMAT3, Y_RNA, AC076966.2.
- chr3:179,169,083–179,169,210, 1 gene, copy number 6: AC076966.1.
- chr7:147,080,934–147,167,572, 3 genes, copy number 9: CNTNAP2-AS1, DUTP3, RANP2.
- chr11:41,394,595–42,163,851, 9 genes, copy number 7 (within-gene range 2–7): AC090138.1, LINC02741, AC021006.1, AC021006.2, LINC01499, AC023442.1, AC023442.3, AC023442.2, LINC02745.
- chr11:60,785,333–97,259,987, 1,124 genes, copy number 6–9 (broad region; genes not listed).
- chr12:11,391,540–11,895,377, 11 genes, copy number 5 (within-gene range 1–5): PRB2, AC078950.1, HIGD1AP8, AC007450.4, AC007450.3, DDX55P1, AC007450.2, AC007450.1, RNU7-60P, LINC01252, ETV6.
- chr12:15,803,164–16,609,259, 8 genes, copy number 8 (within-gene range 3–8): AC073651.2, STRAP, DERA, EGLN3P1, SLC15A5, MGST1, SUPT16HP1, AC007528.1.
- chr12:19,089,151–20,916,911, 25 genes, copy number 8 (within-gene range 3–8): RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3.
- chr12:20,845,065–20,845,260, 1 gene, copy number 8: AC011604.1.
- chr12:24,566,964–25,195,162, 16 genes, copy number 7 (within-gene range 3–7): LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94.
- chr14:22,415,362–23,326,185, 121 genes, copy number 5 (broad region; genes not listed).
- chr14:32,329,298–43,541,826, 150 genes, copy number 6 (broad region; genes not listed).
- chr14:44,444,747–48,228,216, 39 genes, copy number 6: LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1, RNU6-552P, DNAJC19P9, AL162632.3, AL162632.1, AL162632.2, AL139354.1, LINC02303, LINC00871, RPL10L, MDGA2, AL359951.1, RPA2P1, RPL13AP2, RPS15AP3, MIR548Y, LINC00648, AL121576.1, AL359212.1, AL512358.1.
- chr14:49,373,966–52,129,625, 97 genes, copy number 6 (broad region; genes not listed).
- chr14:56,633,244–59,576,812, 59 genes, copy number 6 (within-gene range 3–6): AL161757.2, AL161757.5, AL161757.1, AL161757.3, OTX2, OTX2-AS1, AL161757.4, RN7SL461P, RNU6-1204P, AL137100.3, RPL3P3, AL137100.1, AL137100.2, AL391152.1, EXOC5, AP5M1, AL355834.2, AL355834.1, NAA30, CCDC198, SLC35F4, AL161804.1, AL136520.1, RN7SKP99, AL049838.1, ARMH4, AL121579.2, UBA52P3, RN7SL598P, AL121579.1, ACTR10, PSMA3, AL132989.1, PSMA3-AS1, HMGB1P14, LINC00216, RNU6-341P, ARID4A, AL139021.2, TOMM20L, AL139021.1, TIMM9, KIAA0586, Y_RNA, HSBP1P1, HNRNPCP1, RPL9P5, DACT1, LINC01500, AL049873.1, AL049873.2, AKR1B1P5, PPIAP5, DAAM1, GPR135, L3HYPDH, AL121694.1, JKAMP, CCDC175.
- chr14:60,981,114–63,102,037, 24 genes, copy number 6 (within-gene range 3–6): SLC38A6, PRKCH, TMEM30B, AL359220.1, AL355916.3, AL355916.2, LINC01303, AL355916.1, HIF1A-AS1, HIF1A, HIF1A-AS3, AL137129.1, SNAPC1, AL137918.1, SYT16, COX4I1P1, AL390816.1, AL390816.2, LINC00643, LINC00644, AL390816.3, AL389895.1, ATP5F1AP4, KCNH5.
- chr14:64,388,031–65,062,652, 22 genes, copy number 5 (within-gene range 3–5): MTHFD1, AL122035.1, AL122035.2, ZBTB25, AKAP5, ZBTB1, AL049869.2, AL049869.3, HSPA2, PPP1R36, AL049869.1, NUP50P1, PLEKHG3, SPTB, MIR7855, RPPH1-2P, CHURC1, CHURC1-FNTB, GPX2, RAB15, FNTB, AL139022.2.
- chr14:67,533,290–68,730,218, 29 genes, copy number 6 (within-gene range 3–6): PLEKHH1, PIGH, AL132640.1, AL132640.2, AL132640.3, Y_RNA, ARG2, AL049779.4, VTI1B, COX7A2P1, RNA5SP386, AL049779.1, RDH11, RDH12, RN7SL369P, RPL21P9, ZFYVE26, AL049779.3, RN7SL213P, AL049779.2, RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3, AL121820.2.
- chr14:71,320,449–71,741,229, 1 gene, copy number 5 (within-gene range 3–5): SIPA1L1.
- chr14:71,586,269–75,202,169, 108 genes, copy number 5 (broad region; genes not listed).
- chr14:78,059,942–78,060,278, 1 gene, copy number 6: FXNP1.
- chr14:78,177,803–78,283,376, 3 genes, copy number 6: RNA5SP388, RPS26P48, AF099810.1.
- chr14:80,476,983–106,875,071, 809 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 560. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
